Gene-level copy-number profile of tumor specimen TCGA-L5-A88W-01A from TCGA case TCGA-L5-A88W, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIA; Tumor grade: GX; Age at diagnosis: 67.7 years (24,716 days).
Specimen TCGA-L5-A88W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.98043006-8d43-4e60-bffd-89f686ba2759.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-L5-A88W-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c9ba846e-2d51-4f0e-a22c-d106976554c4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 2,402; copy number 2: 57,413; copy number 3: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-L5-A88W-01A-11D-A350-01): tumor purity 0.71, ploidy 2, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:87,267,883–87,391,931, 1 gene (within-gene range 0–2): RASA1.
- chr5:87,318,416–87,412,930, 1 gene (within-gene range 0–2): CCNH.
- chr5:87,420,341–87,420,447, 1 gene: RNU6-727P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 15. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
